Somatic mutation profile of tumor specimen ALCH-B3ZX-TTP1-A (aliquot ALCH-B3ZX-TTP1-A-3-0-D-A80D-36) from ALCHEMIST case ALCH-B3ZX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.7 years (23,997 days).
Specimen ALCH-B3ZX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5e06009-6760-4493-b131-ec4221353e8d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3ZX-NB1-A (Blood Derived Normal), aliquot ALCH-B3ZX-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46cd5021-2060-4b1e-ba23-2721b7fdaa6d

The open-access MAF lists 550 somatic variants for this specimen: 381 protein-altering or splice-affecting, 108 silent, 61 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 324, Silent 108, Intron 32, Nonsense Mutation 25, Splice Site 15, 3'UTR 10, Splice Region 9, Frame Shift Del 6, 5'Flank 6, RNA 6, 5'UTR 5, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MET | c.3280C>T p.H1094Y | Missense Mutation (SNP) | VAF 151/595 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913244, CM993668, COSV59256829; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RUNX1 | c.877C>T p.R293* (on ENST00000344691 / NM_001001890.3; = p.R320* on NM_001754.5) | Nonsense Mutation (SNP) | VAF 22/140 reads (16%) | catalogued as rs1569008655, CM086912, COSV55867803; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SAMHD1 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 43/280 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs515726145, CM093963, COSV99483854; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 33/112 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABHD18 | c.937A>T p.N313Y (on ENST00000398965 / NM_001039717.2; = p.N220Y on NM_025097.2 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.266); catalogued as COSV101180814; called by muse, mutect2, varscan2
- ACTN2 | c.1029C>G p.I343M | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV63978687; called by muse, mutect2
- ADCY5 | c.2513G>A p.G838E | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as COSV100567914; called by muse, mutect2, varscan2
- ADGRG2 | c.2819C>G p.S940C (on ENST00000379869 / NM_001079858.3; = p.S937C on NM_005756.4) | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61338720; called by muse, mutect2, varscan2
- ALDOB | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs1028676017; called by muse, mutect2, varscan2
- ANO4 | c.2734G>A p.D912N (on ENST00000392977 / NM_001286615.2; = p.D877N on NM_178826.4) | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.199); catalogued as COSV54604791; called by muse, mutect2
- APLF | c.1253G>T p.R418L | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs377389138; called by muse, mutect2, varscan2
- AQR | c.3400G>C p.D1134H | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1566980022; called by muse, mutect2
- ARPP21 | c.1508C>A p.P503H | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1180224054, COSV51800956; called by muse, mutect2, varscan2
- ARSL | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.042); catalogued as rs750673516, COSV66966069; called by muse, mutect2, varscan2
- ATCAY | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.993); catalogued as rs372708763; called by muse, mutect2, varscan2
- AUTS2 | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated, low confidence (0.41); PolyPhen probably damaging (0.978); catalogued as rs1180336046; called by muse, varscan2
- B3GNTL1 | c.545G>T p.W182L | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs987911313; called by muse, mutect2, varscan2
- C1orf94 | c.1361C>A p.A454E (on ENST00000488417 / NM_001134734.2; = p.A264E on NM_032884.5) | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as rs751301476; called by muse, mutect2, varscan2
- C3orf20 | c.1600G>T p.V534L | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV53782353; called by muse, mutect2, varscan2
- C4BPA | c.623C>T p.S208L | Missense Mutation (SNP) | VAF 11/196 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as COSV65536256; called by muse, mutect2
- CACNA1S | c.5345C>T p.P1782L | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.255); catalogued as rs1161249413; called by muse, mutect2, varscan2
- CCDC58 | c.115C>G p.P39A | Missense Mutation (SNP) | VAF 27/229 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV52246332; called by muse, mutect2, varscan2
- CCT8L2 | c.257C>A p.A86E | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1339835823; called by muse, mutect2, varscan2
- CDH9 | c.1195G>T p.G399C | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50262194; called by muse, mutect2
- CLDN17 | c.536G>T p.G179V | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1275482880, COSV99729474; called by muse, mutect2, varscan2
- CLDN17 | c.535G>A p.G179R | Missense Mutation (SNP) | VAF 25/199 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54524465; called by muse, mutect2, varscan2
- CNTN3 | c.1627G>A p.D543N | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.055); catalogued as COSV55176206; called by muse, mutect2
- CNTN6 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.814); catalogued as rs146432604, COSV63181334; called by muse, mutect2, varscan2
- COL5A1 | c.4654G>T p.G1552C | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65666947; called by muse, mutect2, varscan2
- COL7A1 | c.1351G>T p.E451* | Nonsense Mutation (SNP) | VAF 12/71 reads (17%) | catalogued as COSV100096970; called by muse, mutect2, varscan2
- CRB1 | c.2972A>T p.H991L | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as rs1400574905, CM083611; called by muse, mutect2, varscan2
- CRNKL1 | c.226G>A p.V76I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | PolyPhen benign (0.007); catalogued as rs1453072438; called by muse, mutect2, varscan2
- DAB2 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs868674848; called by muse, mutect2, varscan2
- DAD1 | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as rs1237707271, COSV51663966; called by muse, mutect2, varscan2
- DAZAP1 | c.546+2T>C p.X182_splice | Splice Site (SNP) | VAF 27/74 reads (36%) | catalogued as COSV51834402; called by muse, mutect2, varscan2
- DAZAP2 | c.439G>T p.V147F | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs144235964, COSV66312995; called by muse, mutect2, varscan2
- DNAH17 | c.11468C>T p.A3823V | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.575); catalogued as rs1312072464; called by muse, mutect2, varscan2
- DSEL | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 52/236 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs752854439; called by muse, mutect2, varscan2
- DYNC1H1 | c.4514C>T p.S1505L | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.243); catalogued as rs766475544, COSV100795058; called by muse, mutect2, varscan2
- EGF | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 19/195 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.338); catalogued as rs747320674, COSV99491269; called by muse, mutect2, varscan2
- EGFLAM | c.207+1G>A p.X69_splice | Splice Site (SNP) | VAF 18/40 reads (45%) | catalogued as rs1395835560; called by muse, mutect2, varscan2
- EPB41L4A | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 6/154 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0.025); catalogued as COSV54872409; called by muse, mutect2
- ERAL1 | c.537-3C>A | Splice Region (SNP) | VAF 16/103 reads (16%) | catalogued as COSV99650516; called by muse, mutect2, varscan2
- ERCC4 | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.099); catalogued as rs1485867164; called by muse, mutect2, varscan2
- FAM160A1 | c.2299G>A p.E767K | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs369369452; called by muse, mutect2, varscan2
- FAM170A | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.264); catalogued as COSV58923993; called by muse, mutect2
- FBN2 | c.8232C>A p.Y2744* | Nonsense Mutation (SNP) | VAF 17/156 reads (11%) | catalogued as COSV52518830; called by muse, mutect2, varscan2
- FGD4 | c.93G>C p.W31C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.883); catalogued as rs1477570180; called by muse, mutect2, varscan2
- FLII | c.3577G>A p.D1193N | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767962854; called by muse, mutect2, varscan2
- FMO1 | c.726G>T p.M242I | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.186); catalogued as COSV100707696; called by muse, mutect2, varscan2
- FOXD4L5 | c.278del p.P93Rfs*70 | Frame Shift Del (DEL) | VAF 10/80 reads (13%) | catalogued as COSV66241365; called by mutect2, pindel, varscan2
- FRRS1 | c.1555G>C p.G519R | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54926081; called by muse, mutect2, varscan2
- GABRA2 | c.493G>T p.E165* | Nonsense Mutation (SNP) | VAF 12/166 reads (7%) | catalogued as COSV62914606; called by muse, mutect2
- GPR119 | c.813C>G p.N271K | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52275171; called by muse, mutect2
- GPR32 | c.118G>T p.G40W | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.503); catalogued as COSV99567181; called by muse, mutect2, varscan2
- GPRIN2 | c.892G>T p.G298C | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.874); catalogued as rs148764984; called by muse, mutect2, varscan2
- GRID1 | c.1508G>T p.G503V | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60017436; called by muse, mutect2, varscan2
- HBA1 | c.326C>G p.T109S | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.122); catalogued as CM151663; called by muse, mutect2, varscan2
- HEXA | c.1524G>A p.L508= | Splice Region (SNP) | VAF 11/199 reads (6%) | catalogued as COSV51506398; called by muse, mutect2
- IGSF1 | c.1592C>A p.A531D | Missense Mutation (SNP) | VAF 44/68 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as CM164143; called by muse, mutect2, varscan2
- IGSF21 | c.157C>A p.R53S | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.346); catalogued as rs375768650; called by muse, mutect2, varscan2
- IQSEC3 | c.3365C>A p.T1122N | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as rs962509509; called by mutect2, varscan2
- ITGA11 | c.91C>G p.R31G | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as COSV100241481, COSV59882854; called by muse, mutect2, varscan2
- KCNK4 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.021); catalogued as rs146535799; called by mutect2, varscan2
- KIDINS220 | c.3991G>A p.E1331K | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV56752111; called by muse, mutect2, varscan2
- KLHDC2 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1007827129, COSV53587252; called by muse, mutect2, varscan2
- KLK7 | c.694C>A p.P232T | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58343973; called by muse, mutect2, varscan2
- L1TD1 | c.931G>C p.E311Q | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs1180526146; called by muse, mutect2, varscan2
- LAMA1 | c.6748G>T p.V2250F | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as rs933148971, COSV67545286; called by muse, mutect2, varscan2
- LAMA3 | c.3341A>T p.Q1114L | Missense Mutation (SNP) | VAF 62/256 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV100557736; called by muse, mutect2, varscan2
- LAMC1 | c.1594_1595del p.D532Wfs*3 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | catalogued as rs766731876; called by pindel, varscan2
- LCMT1 | c.26C>G p.S9C | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.243); catalogued as COSV66727050; called by mutect2, varscan2
- LRCH2 | c.1277C>A p.S426* | Nonsense Mutation (SNP) | VAF 15/64 reads (23%) | catalogued as COSV57753580; called by muse, mutect2, varscan2
- LRP1B | c.6905G>T p.R2302L | Missense Mutation (SNP) | VAF 46/215 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.205); catalogued as COSV101252990; called by muse, mutect2, varscan2
- LSM14B | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as rs779339184, COSV53380067; called by muse, mutect2, varscan2
- LYST | c.10800G>A p.T3600= | Splice Region (SNP) | VAF 23/207 reads (11%) | catalogued as COSV67707172; called by muse, mutect2, varscan2
- MAP4K2 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as rs139068533, COSV53644017; called by muse, mutect2, varscan2
- MAPK8IP1 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV53796676; called by mutect2, varscan2
- MCPH1 | c.2158G>T p.G720C | Missense Mutation (SNP) | VAF 73/283 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1563292953, COSV100291202; called by muse, mutect2, varscan2
- MMEL1 | c.789C>A p.Y263* | Nonsense Mutation (SNP) | VAF 3/21 reads (14%) | catalogued as COSV56527321; called by muse, varscan2
- MRGPRF | c.883G>A p.G295R | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758658446, COSV99070096; called by muse, mutect2, varscan2
- MTCL1 | c.1042G>T p.D348Y | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs756799865; called by muse, mutect2, varscan2
- MTHFR | c.476-6C>A | Splice Region (SNP) | VAF 13/109 reads (12%) | catalogued as rs1219357233; called by muse, mutect2, varscan2
- MUC16 | c.6353C>A p.A2118E | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV67476661; called by muse, mutect2, varscan2
- NAF1 | c.1234C>T p.Q412* | Nonsense Mutation (SNP) | VAF 23/188 reads (12%) | catalogued as COSV56803436; called by muse, mutect2, varscan2
- NEU4 | c.313G>A p.V105M (on ENST00000391969 / NM_001167602.3; = p.V117M on NM_080741.4) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs374522008; called by muse, mutect2, varscan2
- NKX2-6 | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as rs904420391; called by muse, mutect2, varscan2
- NOL6 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs774814675, COSV99954658; called by muse, mutect2, varscan2
- NPL | c.778+7G>A | Splice Region (SNP) | VAF 16/296 reads (5%) | catalogued as COSV99277442; called by muse, mutect2
- NXPH2 | c.107A>T p.D36V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.637); catalogued as COSV99739988; called by muse, mutect2, varscan2
- OR2F2 | c.70C>G p.Q24E | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs781451267; called by muse, mutect2, varscan2
- OR5F1 | c.580C>A p.L194M | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.329); catalogued as rs752470605, COSV53549115; called by muse, mutect2, varscan2
- OR6K3 | c.440G>T p.R147L (on ENST00000368146; = p.R131L on NM_001005327.2) | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.587); catalogued as rs140112633; called by muse, mutect2, varscan2
- OR6Y1 | c.379C>G p.R127G | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100225223; called by muse, mutect2, varscan2
- OSBPL1A | c.1092+1G>T p.X364_splice | Splice Site (SNP) | VAF 40/140 reads (29%) | catalogued as COSV100112557; called by muse, mutect2, varscan2
- OTOL1 | c.968G>T p.G323V | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60008498; called by muse, mutect2, varscan2
- PCDHGB4 | c.802G>C p.D268H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54018210, COSV99531197; called by muse, mutect2, varscan2
- PCM1 | c.729A>G p.I243M | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1371317141; called by muse, mutect2
- PIBF1 | c.1600G>A p.E534K | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58327585; called by muse, mutect2, varscan2
- PIWIL4 | c.1678G>A p.D560N | Missense Mutation (SNP) | VAF 41/216 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs1367931776; called by muse, mutect2, varscan2
- POM121L2 | c.1954G>C p.V652L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV101079206; called by mutect2, varscan2
- PPP1R17 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.223); catalogued as rs1356302730, COSV59612335; called by muse, mutect2
- PRAMEF2 | c.837C>A p.F279L | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as COSV53576665; called by muse, mutect2
- PRAMEF7 | c.1204G>T p.G402W | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as rs1288605057, COSV100435068; called by muse, mutect2, varscan2
- PRDM10 | c.2049A>G p.R683= | Splice Region (SNP) | VAF 4/14 reads (29%) | catalogued as rs186278201; called by muse, varscan2
- PROKR1 | c.1008G>T p.M336I | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV58139775; called by muse, mutect2, varscan2
- PYDC2 | c.78C>G p.F26L | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs868084371, COSV72921378; called by muse, mutect2, varscan2
- RBBP4 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 8/153 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as COSV65132039; called by muse, mutect2
- RBM27 | c.1319C>G p.S440C | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.971); catalogued as COSV54588319; called by muse, mutect2, varscan2
- RGS22 | c.2441C>T p.S814F | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV62669833; called by muse, mutect2, varscan2
- RPS6KA6 | c.2211G>A p.M737I | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV53118648; called by muse, mutect2, varscan2
- SBF2 | c.2812G>A p.E938K | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1344093861; called by muse, mutect2
- SCN7A | c.4798G>C p.E1600Q | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); catalogued as COSV99081459; called by muse, mutect2
- SCN8A | c.396-2A>G p.X132_splice | Splice Site (SNP) | VAF 17/224 reads (8%) | catalogued as COSV61985874; called by muse, mutect2
- SH2B1 | c.1897+8G>A | Splice Region (SNP) | VAF 6/76 reads (8%) | catalogued as rs1207387393; called by muse, mutect2
- SHANK2 | c.1534G>T p.A512S | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.039); catalogued as COSV99573945; called by muse, mutect2, varscan2
- SLC12A5 | c.1397C>G p.S466C (on ENST00000454036 / NM_001134771.2; = p.S443C on NM_020708.5) | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54791921; called by muse, mutect2, varscan2
- SLC8A2 | c.1946G>A p.G649D | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1265271796; called by muse, mutect2, varscan2
- SLITRK3 | c.627G>T p.K209N | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV53850649; called by muse, mutect2, varscan2
- SMIM13 | c.16G>T p.G6W | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as COSV65369158; called by muse, mutect2, varscan2
- SP140 | c.413A>G p.Y138C | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs768601734; called by muse, varscan2
- SPHKAP | c.2996G>T p.R999L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374937865; called by muse, mutect2, varscan2
- SYT1 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV54076309; called by muse, mutect2
- TANC1 | c.5208G>C p.Q1736H | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.862); catalogued as COSV99714184; called by muse, mutect2
- TGFB3 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.043); catalogued as rs752984800; called by muse, mutect2, varscan2
- THNSL2 | c.887A>C p.Q296P | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as COSV100147369; called by muse, mutect2, varscan2
- TIRAP | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV67023715; called by muse, mutect2
- TOP2B | c.4732G>T p.D1578Y (on ENST00000264331 / NM_001330700.2; = p.D1573Y on NM_001068.3) | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.185); catalogued as COSV51968608, COSV51969917, COSV51971143; called by muse, mutect2
- TRAV9-1 | c.179G>A p.G60E | Missense Mutation (SNP) | VAF 52/211 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as rs1380104045; called by muse, mutect2, varscan2
- TRIM42 | c.1604G>A p.R535Q | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs745861203, COSV53885591; called by muse, mutect2, varscan2
- TRPV2 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as rs200402564; called by muse, mutect2, varscan2
- TSC1 | c.694G>T p.E232* | Nonsense Mutation (SNP) | VAF 102/257 reads (40%) | catalogued as rs118203429, CM090915, COSV53773097; ClinVar: not provided; called by muse, mutect2, varscan2
- TYR | c.523C>A p.L175I | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV54478038; called by muse, mutect2, varscan2
- USH2A | c.1651C>A p.R551S | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.214); catalogued as COSV56358147; called by muse, mutect2
- UXS1 | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.267); catalogued as COSV51680217; called by muse, mutect2
- VPS13A | c.8815G>A p.E2939K | Missense Mutation (SNP) | VAF 26/231 reads (11%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.998); catalogued as rs779897222; called by muse, mutect2, varscan2
- WDR72 | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64745534; called by muse, mutect2
- WWC2 | c.635G>T p.G212V | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761056244; called by muse, mutect2, varscan2
- YJU2 | c.786G>T p.R262S | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV53605411; called by muse, mutect2, varscan2
- ZDHHC9 | c.114C>G p.F38L | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.084); catalogued as COSV64096161; called by muse, mutect2
- ZFHX4 | c.2099G>T p.R700L | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51466756, COSV99268536; called by muse, mutect2, varscan2
- ZIM2 | c.805A>G p.I269V | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs1200422310; called by muse, mutect2, varscan2
- ZNF528 | c.1741G>C p.E581Q | Missense Mutation (SNP) | VAF 4/81 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV64619149, COSV64620374; called by muse, mutect2
- ZNF562 | c.265G>C p.E89Q (on ENST00000453372 / NM_001130032.2; = p.E17Q on NM_017656.4) | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs140829241, COSV53335145; called by muse, mutect2, varscan2
- ZNF646 | c.4007C>T p.S1336F | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs756214340; called by muse, mutect2, varscan2
- ZSCAN5B | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.98); catalogued as rs1186025761; called by muse, mutect2
- ZXDC | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs1164325978; called by muse, mutect2, varscan2
- A2ML1 | c.3163G>A p.D1055N | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ABCB11 | c.1367C>A p.P456H | Missense Mutation (SNP) | VAF 13/199 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.681); called by muse, mutect2
- ABCC11 | c.3392G>T p.C1131F | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.029); called by mutect2, varscan2
- ABO | c.729C>G p.F243L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- ACIN1 | c.1591C>G p.L531V | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ACTN2 | c.537-1G>T p.X179_splice | Splice Site (SNP) | VAF 24/157 reads (15%) | called by muse, mutect2, varscan2
- AGBL3 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.034); called by muse, mutect2
- ALKBH2 | c.680A>G p.N227S | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- AMIGO3 | c.550C>A p.H184N | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- AMOTL1 | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- ANKRD53 | c.1549C>T p.H517Y | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- AP3D1 | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | called by muse, mutect2, varscan2
- ASPM | c.10314G>T p.R3438S | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- BABAM2 | c.994C>G p.H332D | Missense Mutation (SNP) | VAF 16/201 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); called by muse, mutect2
- BIVM-ERCC5 | c.648C>G p.I216M | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BMX | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.87); PolyPhen benign (0.001); called by muse, varscan2
- BRWD3 | c.532G>T p.G178W | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C16orf78 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- C1orf52 | c.528A>C p.E176D | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- C3orf20 | c.2592A>T p.E864D | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CA10 | c.271G>T p.G91C | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- CACNG5 | c.197-1G>T p.X66_splice | Splice Site (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2, varscan2
- CADPS | c.1414T>A p.L472M | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CATSPER1 | c.1589A>G p.Q530R | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- CCDC144A | c.2103G>T p.L701F | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- CCNDBP1 | c.429-3C>A | Splice Region (SNP) | VAF 16/124 reads (13%) | called by muse, mutect2, varscan2
- CCNH | c.169T>A p.C57S | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- CECR2 | c.3028A>G p.T1010A (on ENST00000342247 / NM_001290047.2; = p.T826A on NM_001290046.1) | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP152 | c.4722G>T p.W1574C (on ENST00000380950 / NM_001194998.2; = p.W1518C on NM_014985.4) | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- CEP250 | c.2737G>A p.E913K | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2
- CEP250 | c.3897A>T p.E1299D | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- CEP68 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- CHPF2 | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- CIC | c.1240G>T p.G414W | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- CIC | c.1241G>T p.G414V | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- CILK1 | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 23/213 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CLCN2 | c.958G>C p.E320Q | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- CLIP1 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2
- CLTCL1 | c.417G>T p.M139I | Missense Mutation (SNP) | VAF 7/164 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- CNPY3 | c.318G>T p.R106S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CNTN6 | c.1885C>T p.Q629* | Nonsense Mutation (SNP) | VAF 6/122 reads (5%) | called by muse, mutect2
- CPAMD8 | c.2150G>T p.R717L (on ENST00000651564; = p.R670L on NM_015692.5) | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CREB3L3 | c.511G>T p.D171Y | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRPPA | c.979C>T p.L327F (on ENST00000407010 / NM_001368197.1; = p.L277F on NM_001101417.4) | Missense Mutation (SNP) | VAF 14/275 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.23); called by muse, mutect2
- CSF3R | c.1264G>C p.V422L | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- CSMD3 | c.6487G>A p.D2163N (on ENST00000297405 / NM_001363185.1; = p.D2059N on NM_052900.3) | Missense Mutation (SNP) | VAF 28/268 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTAGE1 | c.405G>C p.L135F | Missense Mutation (SNP) | VAF 10/157 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); called by muse, mutect2
- CUL5 | c.446C>G p.S149* | Nonsense Mutation (SNP) | VAF 8/111 reads (7%) | called by muse, mutect2
- CUX1 | c.334G>A p.E112K (on ENST00000292535 / NM_181552.4; = p.E123K on NM_001913.5) | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.664); called by muse, mutect2
- CYFIP1 | c.612C>G p.I204M | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.366); called by muse, mutect2
- DGKZ | c.166C>G p.P56A | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- DLGAP2 | c.441G>T p.M147I | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- DMXL1 | c.2617G>C p.E873Q | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- DNAH1 | c.10136G>A p.S3379N | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.012); called by muse, mutect2
- DNAH11 | c.7092C>A p.S2364R | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.085); called by mutect2, varscan2
- DNAH11 | c.10569-2A>T p.X3523_splice | Splice Site (SNP) | VAF 20/134 reads (15%) | called by muse, mutect2, varscan2
- DNAH9 | c.10693G>A p.E3565K | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DNAJC7 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.026); called by muse, mutect2
- DZANK1 | c.100A>G p.M34V | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- E2F8 | c.1937C>A p.S646* | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | called by muse, mutect2, varscan2
- EBF3 | c.1531A>T p.N511Y (on ENST00000355311 / NM_001375392.1; = p.N502Y on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- EIF3B | c.1066G>C p.G356R | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- EME1 | c.181G>C p.E61Q | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.01); called by muse, mutect2
- EPC2 | c.57C>G p.I19M | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- EPHA8 | c.569C>A p.A190D | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ERMAP | c.1075G>T p.G359W | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAT3 | c.10978G>C p.D3660H | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FN1 | c.6157G>C p.E2053Q | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.877); called by muse, mutect2
- FTMT | c.513C>A p.N171K | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- GCFC2 | c.1808G>A p.R603K | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- GCM1 | c.224C>A p.S75Y | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GCN1 | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.757); called by muse, mutect2
- GLI2 | c.3264C>A p.H1088Q (on ENST00000361492 / NM_001374353.1; = p.H1105Q on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- GPBP1 | c.1201G>A p.D401N | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GPM6A | c.246G>T p.K82N | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPR148 | c.231C>A p.N77K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPR148 | c.232C>A p.Q78K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPR85 | c.879del p.L295* | Frame Shift Del (DEL) | VAF 11/54 reads (20%) | called by mutect2, pindel
- GRID2 | c.1679C>A p.A560D | Missense Mutation (SNP) | VAF 65/217 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRIK2 | c.1564G>T p.V522F | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- GSG1 | c.880C>T p.H294Y (on ENST00000651961 / NM_001080555.4; = p.H258Y on NM_153823.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- GTSF1 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- HACE1 | c.2329G>C p.D777H | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HCST | c.107C>G p.S36* | Nonsense Mutation (SNP) | VAF 7/81 reads (9%) | called by muse, mutect2
- HDAC1 | c.405G>T p.W135C | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HEATR6 | c.865C>G p.P289A | Missense Mutation (SNP) | VAF 61/298 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); called by muse, varscan2
- HIP1 | c.739C>T p.H247Y | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HIVEP2 | c.1763G>T p.R588L | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- HMG20A | c.992A>C p.N331T | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- HOXA6 | c.208G>C p.A70P | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- HRC | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- IFNL3 | c.484C>A p.P162T | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- IKZF1 | c.1139A>T p.K380M | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- IL22RA1 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- ITGA8 | c.2446G>T p.E816* | Nonsense Mutation (SNP) | VAF 34/188 reads (18%) | called by muse, mutect2, varscan2
- IVD | c.81C>A p.F27L (on ENST00000651168; = p.F24L on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2, varscan2
- KAT8 | c.680del p.L227Wfs*62 | Frame Shift Del (DEL) | VAF 4/16 reads (25%) | called by mutect2, varscan2
- KCND3 | c.1575G>A p.M525I | Missense Mutation (SNP) | VAF 26/190 reads (14%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNJ6 | c.233C>A p.T78N | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- KCNT2 | c.1315G>T p.E439* | Nonsense Mutation (SNP) | VAF 11/108 reads (10%) | called by muse, mutect2, varscan2
- KIDINS220 | c.3731G>T p.G1244V | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KIF3A | c.126G>T p.M42I | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- KIR3DL2 | c.655+1G>T p.X219_splice | Splice Site (SNP) | VAF 31/151 reads (21%) | called by muse, mutect2, varscan2
- KPNA1 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 8/167 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); called by muse, mutect2
- KRT5 | c.1440-1G>A p.X480_splice | Splice Site (SNP) | VAF 8/190 reads (4%) | called by muse, mutect2
- KRTAP5-1 | c.76T>A p.S26T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- LBX2 | c.193C>A p.Q65K | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated (0.05); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- LRP1B | c.848A>G p.H283R | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2
- LRRC23 | c.148G>C p.E50Q | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.041); called by muse, mutect2
- LRRC59 | c.589G>C p.E197Q | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LSG1 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.482); called by muse, mutect2
- LTBP3 | c.2175C>G p.F725L | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- M1AP | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.17); called by muse, mutect2
- MAP7D2 | c.1885G>A p.A629T | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- MCF2 | c.1744-1G>A p.X582_splice | Splice Site (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2
- MFAP3 | c.788A>G p.D263G | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.787); called by muse, mutect2
- MFSD8 | c.1294G>A p.V432I | Missense Mutation (SNP) | VAF 13/235 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2
- MIGA1 | c.1084G>C p.E362Q | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2
- MINDY4 | c.827G>T p.S276I | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- MMP12 | c.463G>T p.G155C | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- MON2 | c.1558G>A p.E520K | Missense Mutation (SNP) | VAF 22/268 reads (8%) | SIFT tolerated (0.84); PolyPhen benign (0.005); called by muse, mutect2
- MRGPRX4 | c.960G>T p.L320F | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2
- MUC16 | c.28568dup p.E9524Gfs*51 | Frame Shift Ins (INS) | VAF 5/10 reads (50%) | called by mutect2, varscan2
- MUC4 | c.1387G>A p.G463R | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- MYO3A | c.3220A>T p.R1074* | Nonsense Mutation (SNP) | VAF 29/130 reads (22%) | called by muse, mutect2, varscan2
- NADSYN1 | c.1492C>G p.Q498E | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- NALCN | c.3319G>T p.A1107S | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- NBEAL2 | c.6946G>C p.D2316H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by mutect2, varscan2
- NELL2 | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 34/190 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- NFXL1 | c.1283G>C p.R428T | Missense Mutation (SNP) | VAF 18/177 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NLK | c.739C>G p.Q247E | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.441); called by mutect2, varscan2
- NLRP8 | c.2788G>T p.D930Y | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NPBWR2 | c.956T>G p.L319R | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NPBWR2 | c.224A>C p.K75T | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NR1D2 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); called by muse, mutect2
- NT5DC1 | c.1253-1G>A p.X418_splice | Splice Site (SNP) | VAF 5/52 reads (10%) | called by muse, mutect2
- NUP205 | c.4750C>G p.Q1584E | Missense Mutation (SNP) | VAF 10/271 reads (4%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2
- NUP214 | c.3532A>G p.T1178A | Missense Mutation (SNP) | VAF 72/220 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OBSL1 | c.4300G>T p.G1434W | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- OSTN | c.63C>G p.S21R | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.609); called by muse, mutect2
- OTOL1 | c.967G>T p.G323W | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAPOLG | c.112A>T p.T38S | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.811); called by muse, varscan2
- PAPPA2 | c.2105G>C p.W702S | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PARP10 | c.2110G>T p.D704Y | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PCDHA3 | c.1029C>G p.I343M | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.201); called by muse, mutect2
- PCDHB5 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- PCDHGC4 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.75); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PEX1 | c.847C>G p.L283V | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PEX19 | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PHF20L1 | c.848-4C>G | Splice Region (SNP) | VAF 15/267 reads (6%) | called by muse, mutect2
- PLEKHG4 | c.1727T>A p.L576* | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | called by muse, mutect2, varscan2
- PLEKHN1 | c.919G>T p.E307* (on ENST00000379409; = p.E255* on NM_032129.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2, varscan2
- PLXNB3 | c.13G>T p.A5S | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- POLR3E | c.614G>C p.W205S | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- POU5F1B | c.1073C>G p.S358* | Nonsense Mutation (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- PRDM10 | c.2047-2A>T p.X683_splice | Splice Site (SNP) | VAF 4/13 reads (31%) | called by muse, varscan2
- PREX1 | c.4870-1G>C p.X1624_splice | Splice Site (SNP) | VAF 21/46 reads (46%) | called by muse, mutect2, varscan2
- PRKAR1B | c.761C>G p.S254C | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.263); called by muse, mutect2
- PRUNE2 | c.3230C>G p.S1077C | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- PTPRB | c.64C>T p.Q22* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | called by mutect2, varscan2
- PXDNL | c.2588C>T p.A863V | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RAP2A | c.219G>C p.K73N | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.145); called by muse, mutect2
- RASL10B | c.258C>G p.H86Q | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.668); called by muse, mutect2, varscan2
- RGS14 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.027); called by muse, mutect2
- RNF114 | c.336dup p.Y113Ifs*14 | Frame Shift Ins (INS) | VAF 10/47 reads (21%) | called by mutect2, pindel, varscan2
- RNPC3 | c.1325G>A p.R442K | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2
- ROCK1 | c.550C>G p.L184V | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ROR2 | c.1981C>A p.P661T | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RPN2 | c.480-1G>A p.X160_splice | Splice Site (SNP) | VAF 22/286 reads (8%) | called by muse, mutect2
- RPRD1B | c.451C>T p.Q151* | Nonsense Mutation (SNP) | VAF 8/150 reads (5%) | called by muse, mutect2
- RSF1 | c.4109C>T p.S1370L | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- RYR1 | c.2309T>A p.F770Y | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEMA3C | c.1439T>A p.F480Y | Missense Mutation (SNP) | VAF 71/212 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SESN1 | c.886G>C p.E296Q (on ENST00000356644 / NM_001199933.1; = p.E355Q on NM_014454.3) | Missense Mutation (SNP) | VAF 11/173 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SETD2 | c.6350C>G p.S2117C | Missense Mutation (SNP) | VAF 6/121 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SFXN4 | c.547C>G p.Q183E | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- SH3D21 | c.257G>A p.R86K | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.05); called by muse, mutect2
- SHROOM2 | c.4378G>C p.E1460Q | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SHROOM2 | c.4486G>C p.D1496H | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- SKIDA1 | c.856C>T p.H286Y | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.006); called by muse, varscan2
- SLC44A5 | c.409A>G p.K137E | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC6A15 | c.266A>G p.Y89C | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SMYD2 | c.206del p.K69Sfs*38 | Frame Shift Del (DEL) | VAF 17/92 reads (18%) | called by mutect2, pindel, varscan2
- SNX7 | c.1042G>T p.V348F | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by mutect2, varscan2
- SPTA1 | c.4812T>A p.N1604K | Missense Mutation (SNP) | VAF 51/297 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SPX | c.166G>T p.D56Y | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- SRCIN1 | c.2066G>C p.R689P (on ENST00000621492; = p.R655P on NM_025248.3) | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- SRSF1 | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- STARD9 | c.1804G>A p.E602K | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STXBP5L | c.2579del p.G860Efs*4 | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | called by mutect2, pindel, varscan2
- SYCE1L | c.402C>A p.H134Q | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- SYNE2 | c.1169C>A p.P390Q | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- SYTL4 | c.111-1G>T p.X37_splice | Splice Site (SNP) | VAF 11/21 reads (52%) | called by muse, mutect2, varscan2
- TAF1 | c.771G>T p.E257D (on ENST00000373790 / NM_138923.4; = p.E278D on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- TANC1 | c.5413G>A p.E1805K | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); called by muse, mutect2
- TDRD5 | c.2428C>G p.H810D | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TENM1 | c.8101G>T p.V2701F | Missense Mutation (SNP) | VAF 32/51 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- TENM4 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- TEX15 | c.5454T>A p.F1818L (on ENST00000256246; = p.F2201L on NM_001350162.2) | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- THEMIS | c.1287C>A p.Y429* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
- TMEM94 | c.1544C>T p.S515F | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TMX2 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- TNFRSF10A | c.320C>G p.S107* | Nonsense Mutation (SNP) | VAF 36/184 reads (20%) | called by muse, mutect2, varscan2
- TOPBP1 | c.3454G>A p.E1152K | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- TOX4 | c.1181T>G p.V394G | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.013); called by mutect2, varscan2
- TRGV1 | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 7/160 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRHDE | c.658G>A p.V220M | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- TRIM39 | c.470G>T p.C157F | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TRIM58 | c.796G>T p.A266S | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRPC5 | c.1642G>C p.D548H | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.72); called by muse, mutect2
- TTN | c.38758G>A p.D12920N (on ENST00000591111; = p.D5496N on NM_003319.4) | Missense Mutation (SNP) | VAF 14/98 reads (14%) | PolyPhen probably damaging (0.998); called by muse, mutect2
- TTN | c.3520G>A p.E1174K (on ENST00000591111; = p.E1128K on NM_003319.4) | Missense Mutation (SNP) | VAF 18/196 reads (9%) | PolyPhen possibly damaging (0.894); called by muse, varscan2
- TUBB6 | c.359T>G p.V120G | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.903); called by muse, mutect2
- TYR | c.524T>A p.L175H | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UNC80 | c.6140G>A p.R2047Q | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- USP3 | c.857C>G p.S286* | Nonsense Mutation (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
- VAV2 | c.851G>T p.G284V (on ENST00000371850 / NM_001134398.2; = p.G279V on NM_003371.4) | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by mutect2, varscan2
- VCAM1 | c.1927G>A p.D643N | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.89); called by muse, mutect2
- WWC1 | c.425A>G p.Q142R | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- YTHDC2 | c.2500G>A p.D834N | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- ZBBX | c.451G>T p.E151* | Nonsense Mutation (SNP) | VAF 25/137 reads (18%) | called by muse, mutect2, varscan2
- ZNF197 | c.742G>C p.E248Q | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.285); called by muse, mutect2
- ZNF273 | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- ZNF335 | c.2311G>A p.D771N | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.244); called by muse, mutect2
- ZNF341 | c.982G>C p.D328H (on ENST00000375200 / NM_001282935.1; = p.D321H on NM_032819.4) | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.921); called by muse, mutect2
- ZNF554 | c.1156G>T p.G386W | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF554 | c.1157G>T p.G386V | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ZNF654 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZNF699 | c.41G>A p.R14K | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2
- ZNF790 | c.1015G>C p.E339Q | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- ZNF790 | c.485G>A p.R162K | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- ZNF845 | c.2173G>T p.G725C | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ZNF853 | c.1581T>A p.N527K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- ZZEF1 | c.7519G>A p.E2507K | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.73); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- ABCA8 | c.4479G>A p.L1493= | Silent (SNP) | VAF 7/128 reads (5%) | catalogued as COSV52199216; called by muse, mutect2
- ACAP2 | c.475C>T p.L159= | Silent (SNP) | VAF 10/142 reads (7%) | called by muse, mutect2
- ACSL4 | c.675C>T p.I225= (on ENST00000340800 / NM_022977.2; = p.I184= on NM_004458.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 46/86 reads (53%) | catalogued as COSV100538283, COSV100538680; called by muse, mutect2, varscan2
- AFTPH | c.1992T>A p.L664= | Silent (SNP) | VAF 29/94 reads (31%) | called by muse, mutect2, varscan2
- AK5 | c.207A>T p.P69= (on ENST00000354567 / NM_174858.3; = p.P43= on NM_012093.4) | Silent (SNP) | VAF 7/66 reads (11%) | called by muse, mutect2, varscan2
- ANGEL1 | c.48C>T p.L16= | Silent (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2
- ARMH4 | c.1209G>A p.L403= | Silent (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- C2orf50 | c.333T>C p.H111= | Silent (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2, varscan2
- CAPN6 | c.1452G>C p.L484= | Silent (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2, varscan2
- CDHR1 | c.1407C>A p.V469= | Silent (SNP) | VAF 30/79 reads (38%) | called by muse, mutect2, varscan2
- CDK11A | c.420G>A p.K140= (on ENST00000378633 / NM_001313896.2; = p.K150= on NM_024011.4) | Silent (SNP) | VAF 9/94 reads (10%) | catalogued as COSV62264701; called by muse, mutect2
- CEP112 | c.2491C>T p.L831= (on ENST00000392769 / NM_001353127.1; = p.L87= on NM_001037325.3) | Silent (SNP) | VAF 11/181 reads (6%) | called by muse, mutect2
- CFAP61 | c.1371G>T p.R457= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as rs753949877, COSV55646725; called by muse, mutect2, varscan2
- CHAT | c.867G>T p.T289= | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as rs574542737, COSV60319512; called by muse, mutect2, varscan2
- CNGB1 | c.3117G>A p.G1039= | Silent (SNP) | VAF 11/93 reads (12%) | called by muse, mutect2
- COL15A1 | c.276C>A p.A92= | Silent (SNP) | VAF 17/42 reads (40%) | called by muse, mutect2, varscan2
- COL22A1 | c.963C>T p.I321= | Silent (SNP) | VAF 6/61 reads (10%) | called by muse, mutect2
- CSMD2 | c.708G>T p.L236= | Silent (SNP) | VAF 15/109 reads (14%) | catalogued as rs769999757; called by muse, mutect2, varscan2
- CTU2 | c.924G>A p.R308= | Silent (SNP) | VAF 3/24 reads (13%) | called by muse, varscan2
- CYP4F3 | c.1224C>T p.L408= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV55413595; called by muse, mutect2, varscan2
- DDB2 | c.651C>T p.V217= | Silent (SNP) | VAF 7/127 reads (6%) | catalogued as rs1234969885; called by muse, mutect2
- DENND2A | c.2004G>A p.V668= | Silent (SNP) | VAF 24/107 reads (22%) | catalogued as COSV52058784; called by muse, mutect2, varscan2
- DHRS13 | c.345G>T p.R115= | Silent (SNP) | VAF 14/68 reads (21%) | called by muse, mutect2, varscan2
- DLG5 | c.2602C>T p.L868= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as rs765328565; called by muse, mutect2
- DSTYK | c.2253G>T p.L751= | Silent (SNP) | VAF 14/50 reads (28%) | called by muse, mutect2, varscan2
- EHD2 | c.1119G>T p.S373= | Silent (SNP) | VAF 23/108 reads (21%) | catalogued as COSV99622082; called by muse, mutect2, varscan2
- EPRS1 | c.3105A>T p.S1035= | Silent (SNP) | VAF 14/60 reads (23%) | called by muse, mutect2, varscan2
- FAM155B | c.672G>A p.L224= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV52935839; called by muse, mutect2, varscan2
- FAM200B | c.675T>C p.F225= | Silent (SNP) | VAF 62/217 reads (29%) | called by muse, mutect2, varscan2
- FBXO31 | c.1455C>T p.P485= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs754970927; called by muse, mutect2, varscan2
- FRMD4A | c.534T>A p.P178= | Silent (SNP) | VAF 19/61 reads (31%) | called by muse, mutect2, varscan2
- GJB3 | c.405C>T p.L135= | Silent (SNP) | VAF 10/168 reads (6%) | called by muse, mutect2
- GPATCH8 | c.1926G>A p.L642= | Silent (SNP) | VAF 5/61 reads (8%) | called by muse, mutect2
- GRAMD1C | c.1137G>A p.L379= | Silent (SNP) | VAF 10/170 reads (6%) | called by muse, mutect2
- GRIA2 | c.1929C>T p.A643= | Silent (SNP) | VAF 22/210 reads (10%) | called by muse, mutect2
- GRIN2D | c.1233C>G p.L411= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV99616723; called by muse, mutect2, varscan2
- GRIN3A | c.1371C>G p.V457= | Silent (SNP) | VAF 54/162 reads (33%) | catalogued as COSV62457449; called by muse, mutect2, varscan2
- HEXA | c.390G>A p.E130= | Silent (SNP) | VAF 18/264 reads (7%) | called by muse, mutect2
- IFNL3 | c.483C>A p.A161= | Silent (SNP) | VAF 9/19 reads (47%) | called by muse, mutect2, varscan2
- INPPL1 | c.1911C>T p.L637= | Silent (SNP) | VAF 12/96 reads (13%) | called by muse, mutect2, varscan2
- KCNK17 | c.426A>T p.P142= | Silent (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2, varscan2
- KLHL4 | c.963C>T p.L321= | Silent (SNP) | VAF 47/105 reads (45%) | called by muse, mutect2, varscan2
- KSR2 | c.2238G>T p.T746= | Silent (SNP) | VAF 26/127 reads (20%) | called by muse, mutect2, varscan2
- LIPC | c.1359C>A p.I453= | Silent (SNP) | VAF 25/85 reads (29%) | called by muse, mutect2, varscan2
- LRP5 | c.2520G>C p.V840= | Silent (SNP) | VAF 18/67 reads (27%) | called by muse, mutect2, varscan2
- LTBP3 | c.1914C>T p.S638= | Silent (SNP) | VAF 7/63 reads (11%) | called by muse, mutect2, varscan2
- MAP1A | c.4203G>T p.V1401= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV55806790; called by muse, mutect2, varscan2
- MBD1 | c.1110G>A p.Q370= (on ENST00000269468 / NM_001323950.1; = p.Q347= on NM_015845.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/79 reads (10%) | called by muse, mutect2
- MCEMP1 | c.348G>A p.L116= | Silent (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2, varscan2
- MPP1 | c.420C>A p.T140= | Silent (SNP) | VAF 12/59 reads (20%) | called by muse, mutect2, varscan2
- MROH2B | c.1242G>A p.V414= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV68181996; called by muse, mutect2, varscan2
- MTPAP | c.1725G>A p.K575= | Silent (SNP) | VAF 16/203 reads (8%) | called by muse, mutect2
- MUC16 | c.42249C>T p.I14083= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as COSV101109849, COSV66689721; called by muse, mutect2, varscan2
- MUC16 | c.12909C>T p.S4303= | Silent (SNP) | VAF 20/55 reads (36%) | called by muse, mutect2, varscan2
- MUC16 | c.9180C>A p.S3060= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as rs756204334; called by muse, mutect2, varscan2
- MUC4 | c.5241C>T p.V1747= | Silent (SNP) | VAF 13/128 reads (10%) | called by muse, varscan2
- MYH14 | c.3810G>A p.R1270= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV51812214; called by muse, mutect2, varscan2
- MYO10 | c.1167C>G p.L389= | Silent (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
- NBR1 | c.552G>A p.Q184= | Silent (SNP) | VAF 15/117 reads (13%) | catalogued as COSV57833422; called by muse, mutect2, varscan2
- NEFM | c.810G>T p.L270= | Silent (SNP) | VAF 10/204 reads (5%) | called by muse, mutect2
- NEURL4 | c.1710C>T p.I570= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as rs539777055; called by muse, mutect2, varscan2
- NLRP5 | c.2052C>A p.T684= | Silent (SNP) | VAF 31/104 reads (30%) | catalogued as rs1329138726; called by muse, mutect2, varscan2
- NUDT16 | c.99G>A p.G33= | Silent (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2, varscan2
- NUTM1 | c.396A>T p.P132= | Silent (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- OLFM3 | c.510C>T p.I170= (on ENST00000338858 / NM_001288821.1; = p.I150= on NM_058170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/188 reads (5%) | called by muse, mutect2
- OR10S1 | c.291C>A p.G97= | Silent (SNP) | VAF 45/122 reads (37%) | called by muse, mutect2, varscan2
- OR4M1 | c.255C>T p.F85= | Silent (SNP) | VAF 6/132 reads (5%) | catalogued as rs1219450183, COSV100271448, COSV60059940; called by muse, mutect2
- OR5M11 | c.468C>G p.L156= | Silent (SNP) | VAF 6/122 reads (5%) | called by muse, mutect2
- ORAI2 | c.159C>G p.L53= | Silent (SNP) | VAF 9/85 reads (11%) | called by muse, mutect2
- PCDH18 | c.297G>A p.Q99= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV61266665; called by muse, mutect2, varscan2
- PCDHB9 | c.972C>A p.G324= | Silent (SNP) | VAF 15/107 reads (14%) | called by muse, mutect2, varscan2
- PIKFYVE | c.5808C>A p.V1936= | Silent (SNP) | VAF 31/278 reads (11%) | called by muse, mutect2, varscan2
- POLQ | c.4227C>T p.I1409= | Silent (SNP) | VAF 5/73 reads (7%) | called by muse, mutect2
- POLR1A | c.1815G>T p.R605= | Silent (SNP) | VAF 8/59 reads (14%) | called by muse, mutect2, varscan2
- PPFIA3 | c.513G>T p.R171= | Silent (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2, varscan2
- RAB9A | c.267C>T p.V89= | Silent (SNP) | VAF 16/148 reads (11%) | catalogued as rs772882790, COSV54610793; called by muse, mutect2, varscan2
- SBSN | c.954C>G p.A318= | Silent (SNP) | VAF 8/73 reads (11%) | called by muse, mutect2, varscan2
- SENP7 | c.2124G>A p.A708= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as rs377419959; called by muse, mutect2, varscan2
- SH3BP4 | c.666C>T p.V222= | Silent (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2, varscan2
- SKP2 | c.864G>A p.L288= | Silent (SNP) | VAF 10/182 reads (5%) | called by muse, mutect2
- SLC26A4 | c.753C>G p.L251= | Silent (SNP) | VAF 20/242 reads (8%) | catalogued as rs111713323, CD982866, COSV99706594; called by muse, mutect2
- SLC52A1 | c.1257C>A p.S419= | Silent (SNP) | VAF 13/53 reads (25%) | called by muse, mutect2, varscan2
- SLC7A14 | c.1353G>A p.K451= | Silent (SNP) | VAF 14/134 reads (10%) | catalogued as rs752803993; called by muse, mutect2
- SLC7A14 | c.882C>A p.V294= | Silent (SNP) | VAF 9/50 reads (18%) | called by muse, mutect2, varscan2
- SPHKAP | c.2997G>T p.R999= | Silent (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- SRRM4 | c.1131C>A p.V377= | Silent (SNP) | VAF 36/141 reads (26%) | catalogued as COSV57427490; called by muse, mutect2, varscan2
- STARD9 | c.9543G>A p.L3181= | Silent (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- TAPBP | c.24C>G p.L8= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as rs748787510; called by muse, mutect2, varscan2
- TBX19 | c.60C>G p.L20= | Silent (SNP) | VAF 27/139 reads (19%) | called by muse, mutect2, varscan2
- TBX4 | c.786G>A p.L262= | Silent (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2
- TCL1A | c.108C>A p.P36= | Silent (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- TEX15 | c.8369G>A p.*2790= (on ENST00000256246; = p.*3173= on NM_001350162.2) | Silent (SNP) | VAF 7/109 reads (6%) | called by muse, mutect2
- TFDP2 | c.1095G>A p.L365= (on ENST00000489671 / NM_001178139.2; = p.L305= on NM_006286.5) | Silent (SNP) | VAF 10/129 reads (8%) | called by muse, mutect2
- TGM1 | c.1755A>T p.A585= | Silent (SNP) | VAF 13/49 reads (27%) | called by muse, mutect2, varscan2
- TKTL2 | c.156C>G p.L52= | Silent (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
- TMEM132C | c.1587G>A p.Q529= | Silent (SNP) | VAF 7/96 reads (7%) | called by muse, mutect2
- TMEM135 | c.210A>G p.Q70= | Silent (SNP) | VAF 59/315 reads (19%) | catalogued as rs1210264795, COSV100449933; called by muse, mutect2, varscan2
- TNFRSF8 | c.1164C>T p.L388= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs1468449010; called by muse, mutect2, varscan2
- TTN | c.4197G>A p.V1399= (on ENST00000591111; = p.V1353= on NM_003319.4) | Silent (SNP) | VAF 14/240 reads (6%) | called by muse, mutect2
- UBR5 | c.18C>T p.F6= | Silent (SNP) | VAF 11/70 reads (16%) | called by muse, mutect2, varscan2
- UROC1 | c.1329C>A p.S443= | Silent (SNP) | VAF 13/51 reads (25%) | called by muse, mutect2, varscan2
- USP17L4 | c.1089G>C p.L363= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as rs751572842; called by mutect2, varscan2
- VWA5B2 | c.2625T>A p.P875= | Silent (SNP) | VAF 14/68 reads (21%) | called by muse, mutect2, varscan2
- WDR26 | c.1674G>T p.G558= (on ENST00000414423 / NM_001379403.1; = p.G458= on NM_025160.7) | Silent (SNP) | VAF 28/181 reads (15%) | called by muse, mutect2, varscan2
- WIF1 | c.318G>A p.L106= | Silent (SNP) | VAF 27/138 reads (20%) | catalogued as rs1489246637; called by muse, mutect2, varscan2
- ZAN | c.2919G>A p.T973= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as rs1480446365, COSV61811969; called by muse, varscan2
- ZNF516 | c.1854G>T p.S618= | Silent (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- ZNF841 | c.2259A>T p.R753= (on ENST00000426391 / NM_001369830.1; = p.R869= on NM_001136499.1 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as COSV63469842; called by mutect2, varscan2
- AC068587.4 | n.683+5132A>T | Intron (SNP) | VAF 20/199 reads (10%) | called by muse, mutect2, varscan2
- ACAD9 | c.1563+23G>T | Intron (SNP) | VAF 16/66 reads (24%) | called by muse, mutect2, varscan2
- ACYP2 | c.186-37354C>T | Intron (SNP) | VAF 31/86 reads (36%) | called by muse, mutect2, varscan2
- AFMID | c.155-5298G>T | Intron (SNP) | VAF 17/61 reads (28%) | catalogued as COSV59976944; called by muse, mutect2, varscan2
- AGAP3 | c.1020+391C>T | Intron (SNP) | VAF 28/72 reads (39%) | catalogued as rs911391078; called by muse, mutect2
- AGAP3 | c.1020+392G>T | Intron (SNP) | VAF 25/65 reads (38%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73821868 T>A | 5'Flank (SNP) | VAF 62/110 reads (56%) | called by muse, varscan2
- AP000679.1 | n.1088G>T | RNA (SNP) | VAF 19/78 reads (24%) | called by muse, mutect2, varscan2
- C22orf34 | chr22:49626911 G>T | 5'Flank (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2, varscan2
- C7orf65 | n.283A>T | RNA (SNP) | VAF 22/116 reads (19%) | called by muse, mutect2, varscan2
- CCDC110 | c.2461+358_2461+361del | Intron (DEL) | VAF 5/33 reads (15%) | catalogued as rs765965188; called by pindel, varscan2
- CCT6B | c.*6G>A | 3'UTR (SNP) | VAF 4/36 reads (11%) | catalogued as COSV100030570; called by mutect2, varscan2
- CEACAM4 | c.*61G>A | 3'UTR (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2, varscan2
- CFAP74 | c.2176+341C>G | Intron (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2, varscan2
- CLCN2 | c.1086-22G>A | Intron (SNP) | VAF 7/49 reads (14%) | called by muse, varscan2
- CPLANE1 | c.*4393A>T | 3'UTR (SNP) | VAF 16/56 reads (29%) | called by muse, mutect2, varscan2
- CREB5 | c.465-32556G>A | Intron (SNP) | VAF 8/140 reads (6%) | catalogued as COSV63220402; called by muse, mutect2
- DMRT1 | c.*22G>T | 3'UTR (SNP) | VAF 17/65 reads (26%) | called by muse, mutect2, varscan2
- DOCK8 | chr9:214556 C>T | 5'Flank (SNP) | VAF 9/96 reads (9%) | catalogued as rs202148697, COSV66688195; called by muse, mutect2, varscan2
- DSG1 | c.*25T>A | 3'UTR (SNP) | VAF 16/105 reads (15%) | called by muse, mutect2, varscan2
- EHMT1 | c.2505+1090G>A | Intron (SNP) | VAF 16/42 reads (38%) | catalogued as rs887421788; called by mutect2, varscan2
- ESYT1 | c.1474-18G>C | Intron (SNP) | VAF 12/71 reads (17%) | called by muse, mutect2, varscan2
- F13A1 | c.319+55A>G | Intron (SNP) | VAF 12/140 reads (9%) | called by muse, mutect2
- FDXR | c.270+9C>G | Intron (SNP) | VAF 6/55 reads (11%) | catalogued as rs1445989577; called by muse, mutect2, varscan2
- GANC | c.202-3981C>T | Intron (SNP) | VAF 42/190 reads (22%) | called by muse, varscan2
- GH2 | c.456+13C>A | Intron (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2, varscan2
- GLTPP1 | chr11:18188955 G>T | 5'Flank (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2, varscan2
- GNL1 | c.*63C>T | 3'UTR (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2
- GSTZ1 | c.475-57C>G | Intron (SNP) | VAF 13/71 reads (18%) | called by muse, mutect2, varscan2
- HSDL2 | c.-9A>T | 5'UTR (SNP) | VAF 15/49 reads (31%) | called by muse, mutect2, varscan2
- JMJD6 | chr17:76716670 G>A | 3'Flank (SNP) | VAF 5/74 reads (7%) | called by muse, mutect2
- JPH4 | c.1152-982G>C | Intron (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2
- KRT13 | c.1244+41G>T | Intron (SNP) | VAF 14/47 reads (30%) | called by muse, mutect2, varscan2
- LRP4 | c.4448+34G>A | Intron (SNP) | VAF 28/87 reads (32%) | catalogued as rs1244990309; called by mutect2, varscan2
- LRRC37A6P | n.1766C>G | RNA (SNP) | VAF 9/126 reads (7%) | called by muse, mutect2
- MBD1 | c.392+42G>A | Intron (SNP) | VAF 15/114 reads (13%) | called by muse, mutect2, varscan2
- MMAB | c.*492A>G | 3'UTR (SNP) | VAF 31/137 reads (23%) | called by muse, mutect2, varscan2
- MPRIP | c.2163+4086G>T | Intron (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- MTERF4 | c.*921G>C | 3'UTR (SNP) | VAF 15/149 reads (10%) | catalogued as rs1444756099; called by muse, mutect2, varscan2
- MTSS1 | c.1405-152G>C | Intron (SNP) | VAF 11/69 reads (16%) | catalogued as rs1444970272; called by muse, mutect2, varscan2
- MTX1 | chr1:155214664 G>A | 3'Flank (SNP) | VAF 9/108 reads (8%) | called by muse, mutect2
- OXSM | chr3:25789837 C>A | 5'Flank (SNP) | VAF 37/135 reads (27%) | called by muse, mutect2, varscan2
- PA2G4 | c.-151C>T | 5'UTR (SNP) | VAF 19/104 reads (18%) | catalogued as COSV99916883; called by muse, mutect2, varscan2
- PDLIM5 | c.291+62C>A | Intron (SNP) | VAF 56/171 reads (33%) | called by muse, mutect2, varscan2
- POLQ | c.-9G>C | 5'UTR (SNP) | VAF 13/98 reads (13%) | catalogued as COSV99952255; called by muse, mutect2, varscan2
- POLR2F | c.452+983C>T | Intron (SNP) | VAF 4/18 reads (22%) | catalogued as rs370289612; called by muse, mutect2
- PPP1R9A | c.2758-1955G>A | Intron (SNP) | VAF 18/137 reads (13%) | catalogued as COSV56897293; called by muse, mutect2, varscan2
- RTF2 | c.69+1866G>T | Intron (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- SLC1A7 | c.1032-91G>T | Intron (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2, varscan2
- SNCA | c.391-19T>C | Intron (SNP) | VAF 56/177 reads (32%) | called by muse, mutect2, varscan2
- TAFA2 | c.385-10497A>G | Intron (SNP) | VAF 30/133 reads (23%) | called by muse, mutect2, varscan2
- TCAIM | c.-27G>A | 5'UTR (SNP) | VAF 11/71 reads (15%) | catalogued as rs531864716; called by muse, mutect2, varscan2
- TCERG1 | c.-13G>C | 5'UTR (SNP) | VAF 11/41 reads (27%) | called by muse, mutect2, varscan2
- TMEM209 | chr7:130206973 G>A | 5'Flank (SNP) | VAF 19/31 reads (61%) | catalogued as rs1442372550; called by muse, mutect2, varscan2
- TRAPPC3L | c.43-467T>G | Intron (SNP) | VAF 40/131 reads (31%) | called by muse, mutect2, varscan2
- TXNRD3 | n.726A>T | RNA (SNP) | VAF 11/26 reads (42%) | called by muse, mutect2, varscan2
- XIAP | c.*5987_*5988insC | 3'UTR (INS) | VAF 16/45 reads (36%) | called by mutect2, pindel, varscan2
- XIST | n.9281C>T | RNA (SNP) | VAF 11/154 reads (7%) | called by muse, mutect2
- ZBP1 | c.*182G>A | 3'UTR (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- ZNF589 | c.97-3971G>C | Intron (SNP) | VAF 15/64 reads (23%) | called by muse, mutect2, varscan2
- ZNF971P | n.325G>T | RNA (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2, varscan2
